TCGA case TCGA-C5-A1BL — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Medical College of Wisconsin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/03c3fe57-ae85-4e45-9657-c3182ab5e124

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 32 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 32.1 years (11,723 days); Year of diagnosis: 1994; Method of diagnosis: Biopsy; FIGO stage: Stage IB; FIGO staging edition year: 1988; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 25; Lymphatic invasion present: Yes.
   Pathology details: Lymph node involved site: Pelvis, NOS.
   Treatment given: Treatment type: Radiation, Combination; Treatment intent type: Adjuvant; Days to treatment start: 19 days; Days to treatment end: 64 days; Treatment dose: 5,040 cGy; Course number: 1; Treatment anatomic sites: Primary Tumor Field.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.

Follow-up (9 entries)
- Day -5 (preoperative): ECOG performance status: 1.
- Day 1 (preoperative): Days to imaging: 1 day; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Supraclavicular Lymph Node Involvement.
- Day 1 (preoperative): Days to imaging: 1 day; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Parametrium Involvement.
- Day 1 (preoperative): Days to imaging: 1 day; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Bladder Involvement.
- Day 1 (preoperative): Days to imaging: 1 day; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Pelvic Lymph Node Involvement.
- Day 1 (preoperative): Days to imaging: 1 day; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Extra-Pelvic Metastatic Disease.
- Day 1 (preoperative): Days to imaging: 1 day; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Paraaortic Lymph Node Involvement.
- Day 1,479 (post adjuvant therapy): ECOG performance status: 1.
- Days to follow up: 5,271 days (14.4 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Human Papillomavirus (PCR): Positive [Hpv strain: HPV16].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used.
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Live Birth.
- Timepoint category: Prior to Diagnosis; Comorbidities: Human Papillomavirus Infection; Risk factors: Human Papillomavirus Infection.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Induced Abortion.
- Timepoint category: Initial Diagnosis; Weight: 78 kg; Height: 168 cm; BMI: 27.6.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Stillbirth.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Ectopic Pregnancy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Miscarriage.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 12; Tobacco smoking quit year: 1988; Age at onset: 16.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-C5-A1BL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 150 mg.
  Slide TCGA-C5-A1BL-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 20; Percent lymphocyte infiltration: 60; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-C5-A1BL-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-C5-A1BL-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: Tumor free; Live birth pregnancy count: 1; Pregnancies count miscarriage: 0; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Pregnant at diagnosis: No; Total pregnancy count: 1; Tobacco smoking history indicator: 4; Tumor response: Complete response; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0; Lymphovascular invasion: Present; Corpus involvement: Absent; Days to ct scan ab pelvis: 1; Pcr primer pairs: GP5+/GP6+.
- Lymph node location positive pathology names: Pos lymph node location: Pelvic (external iliac, internal iliac, obturator).
- Diagnostic ct result outcomes: Ct scan preop results: Bladder Absent; Ct scan preop results: Extra-Pelvic Metastatic Disease Absent; Ct scan preop results: Parametrium Absent; Ct scan preop results: Paraaortic Nodes Absent; Ct scan preop results: Pelvic Nodes Absent; Ct scan preop results: Supraclavicular Absent.
- Human papillomavirus types: HPV types positive: HPV 16.
- Follow-up form 1: Tumor status: Tumor free; Performance status timing: Post-Adjuvant Therapy; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; Radiation adjuvant indicator: Yes; Brachytherapy type: HDR; Days to brachytherapy begin occurrence: 33; Days to brachytherapy end occurrence: 54; Brachytherapy total dose point a: 8867; Brachytherapy status: Completed as planned; Radiation therapy xrt type: External beam radiation; New tumor event diagnosis indicator: No.
- Follow-up form 1, Radiation supplemental: Radiation therapy dose paraaortic nodes: 4500; Radiation therapy status: Completed as Planned; Chemo concurrent reason not other: On randomized study and received arm without chemotherapy.
- Follow-up form 2: Lost to follow-up: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 5,271 days; disease-specific survival: no event (censored), 5,271 days; disease-free interval: no event (censored), 5,271 days; progression-free interval: no event (censored), 5,271 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-C5-A1BL-01A-11D-A13V-01): tumor purity 0.62, ploidy 2.07, whole-genome doublings 0.
